Somatic mutation profile of tumor specimen HTMCP-03-06-02446-01A (aliquot HTMCP-03-06-02446-01A-01D-10409) from CGCI case HTMCP-03-06-02446, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenosquamous carcinoma; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 56.3 years (20,574 days).
Specimen HTMCP-03-06-02446-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46749384-cbdc-4cdc-be6a-a599f4a30d1c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02446-10A (Blood Derived Normal), aliquot HTMCP-03-06-02446-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf0e353b-f00e-4ce8-a633-2113b659c2f7

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 12/93 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH10 | c.2297G>A p.R766Q | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs137884653; called by muse, mutect2
- TENM1 | c.6139C>T p.R2047* | Nonsense Mutation (SNP) | VAF 8/170 reads (5%) | catalogued as COSV100950519, COSV64440149; called by muse, mutect2
- UNC5D | c.955G>A p.V319I | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.381); catalogued as rs545883862, COSV54802501; called by mutect2, varscan2
- CNTN4 | c.575A>G p.Y192C | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ECT2 | c.1552G>A p.D518N (on ENST00000392692 / NM_001349098.2; = p.D487N on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- FXR1 | c.588G>C p.L196F | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NF1 | c.8357C>T p.A2786V (on ENST00000358273 / NM_001042492.3; = p.A2765V on NM_000267.3) | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- ZNF729 | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AKAP13 | c.6576G>A p.V2192= (on ENST00000394518 / NM_007200.5; = p.V2196= on NM_006738.6) | Silent (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+11091G>C | Intron (SNP) | VAF 11/152 reads (7%) | catalogued as rs1565814361; called by muse, mutect2
- NBPF9 | c.2476+740G>C | Intron (SNP) | VAF 16/272 reads (6%) | called by muse, mutect2
